Somatic mutation profile of tumor specimen TCGA-EE-A2MI-06A (aliquot TCGA-EE-A2MI-06A-11D-A197-08) from TCGA case TCGA-EE-A2MI, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.3 years (21,662 days).
Specimen TCGA-EE-A2MI-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f51baa4b-0b68-4b27-9203-f39667753d5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MI-10A (Blood Derived Normal), aliquot TCGA-EE-A2MI-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c11b029e-0f23-4f9f-af37-d0cbd25541ea

The open-access MAF lists 1,301 somatic variants for this specimen: 837 protein-altering or splice-affecting, 431 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 770, Silent 431, Nonsense Mutation 42, Intron 13, Splice Region 11, RNA 10, Frame Shift Del 7, Splice Site 4, 5'Flank 4, 3'UTR 3, 3'Flank 2, Translation Start Site 1.

Variants (750 of 1,301; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5881G>A p.G1961R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142253670, HM060037; ClinVar: likely pathogenic; called by muse, mutect2
- UCHL1 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52651371; called by muse, mutect2, varscan2
- USH2A | c.13576C>T p.R4526* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as rs1003869920, CM115977, COSV56326318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV50988861; called by muse, mutect2, varscan2
- ABCA12 | c.1374G>A p.M458I (on ENST00000272895 / NM_173076.3; = p.M140I on NM_015657.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1265368298, COSV55949349; called by muse, mutect2, varscan2
- ABCA3 | c.170A>T p.Y57F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV57049561, COSV57056989; called by muse, mutect2, varscan2
- ABCA6 | c.2230C>T p.L744F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52642008; called by muse, mutect2
- ABCC12 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.07); catalogued as COSV60916309; called by muse, mutect2, varscan2
- ABCC6 | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.287); catalogued as rs778911783, COSV52746539; called by muse, mutect2, varscan2
- ABLIM1 | c.247del p.A83Pfs*57 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as COSV53315821; called by mutect2, pindel*, varscan2
- ACAN | c.2717C>T p.S906F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61365382; called by muse, mutect2, varscan2
- ACE | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52010627; called by muse, mutect2, varscan2
- ACOX2 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV57150053; called by muse, mutect2, varscan2
- ACOX3 | c.1855G>A p.G619R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); catalogued as COSV62713018; called by muse, mutect2
- ACSM2B | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs769565102, COSV61659083, COSV61659638; called by muse, mutect2, varscan2
- ADAM11 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1288967497, COSV52348269, COSV52350162; called by muse, mutect2, varscan2
- ADAMTS16 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759325136, COSV56999273, COSV99941416; called by muse, mutect2, varscan2
- ADAMTS6 | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 48/163 reads (29%) | catalogued as COSV66862531; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3467G>A p.G1156E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV54459215; called by muse, mutect2, varscan2
- ADCY8 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs147685814, COSV53894976; called by muse, mutect2, varscan2
- ADGRF5 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51937565; called by muse, mutect2, varscan2
- ADGRV1 | c.8108G>A p.G2703E | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748918228, COSV67991119; called by muse, mutect2, varscan2
- AFF2 | c.3620G>A p.G1207E | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53977536, COSV53999460; called by muse, mutect2, varscan2
- AGBL1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.71); catalogued as COSV69806966; called by muse, mutect2
- AIFM3 | c.607+2T>C p.X203_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV59001730; called by muse, mutect2, varscan2
- AKAP8L | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.435); catalogued as COSV68474081; called by muse, mutect2, varscan2
- AKR1B10 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs148486050, COSV62055186; called by muse, mutect2, varscan2
- AKR1D1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54339109; called by muse, mutect2, varscan2
- ALS2 | c.2833C>T p.H945Y | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs768066388, COSV51890214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER1 | c.2935C>T p.Q979* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV57658283; called by muse, mutect2, varscan2
- ANAPC2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV58808463; called by muse, mutect2, varscan2
- ANGPT1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52449117; called by muse, mutect2, varscan2
- ANGPT4 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as COSV67922363; called by muse, mutect2
- ANGPTL1 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52367376; called by muse, mutect2, varscan2
- ANKRD30A | c.1156G>A p.E386K (on ENST00000611781; = p.E330K on NM_052997.2) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.292); catalogued as COSV64608348; called by muse, varscan2
- ANO2 | c.964G>A p.D322N (on ENST00000356134 / NM_001278597.3; = p.D326N on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs781540782, COSV59007575; called by mutect2, varscan2
- ANXA9 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs150067239; called by muse, mutect2, varscan2
- AOC3 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs376688071; called by muse, mutect2, varscan2
- APBA1 | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs947325202, COSV55232858; called by muse, mutect2, varscan2
- APCS | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.376); catalogued as COSV54817841, COSV54817863; called by muse, mutect2, varscan2
- APOB | c.10055C>T p.T3352I | Missense Mutation (SNP) | VAF 116/405 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs767624020, COSV51944878; called by muse, mutect2, varscan2
- APOB | c.8065C>T p.P2689S | Missense Mutation (SNP) | VAF 149/490 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51944893; called by muse, mutect2, varscan2
- APOB | c.5203G>A p.G1735R | Missense Mutation (SNP) | VAF 219/629 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173916995, COSV51944913; called by muse, mutect2, varscan2
- APOBR | c.3028C>T p.R1010W (on ENST00000431282; = p.R1019W on NM_018690.4) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs373411584, COSV60492482; called by muse, mutect2, varscan2
- ARFGEF3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52464467; called by muse, mutect2, varscan2
- ARFGEF3 | c.5900G>A p.S1967N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52464490; called by muse, mutect2
- ARFIP2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs374563605, COSV54447705; called by muse, mutect2, varscan2
- ARHGAP10 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.439); catalogued as COSV60603192; called by muse, mutect2, varscan2
- ARHGAP44 | c.387G>A p.E129= | Splice Region (SNP) | VAF 13/28 reads (46%) | catalogued as COSV52397610; called by muse, mutect2, varscan2
- ARHGEF15 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV62725890; called by muse, mutect2, varscan2
- ARMC4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV53466312; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ASAH2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV61484079; called by muse, mutect2, varscan2
- ASB15 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as COSV51928003; called by muse, mutect2, varscan2
- ASB2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100279560, COSV60110553; called by muse, mutect2, varscan2
- ASB5 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56672832; called by muse, mutect2, varscan2
- ASCC3 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61231438; called by muse, mutect2, varscan2
- ASTN2 | c.1724G>A p.G575E (on ENST00000313400 / NM_001365069.1; = p.G524E on NM_014010.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57800281; called by muse, mutect2, varscan2
- ASTN2 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs762528231, COSV100524617, COSV100529647; called by muse, mutect2, varscan2
- ASXL2 | c.1646C>T p.T549I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV55463724; called by muse, mutect2, varscan2
- ASXL3 | c.3737C>T p.S1246L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs552703360, COSV52459613; called by muse, mutect2, varscan2
- ASZ1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52915023; called by muse, mutect2, varscan2
- ATL1 | c.1643A>G p.E548G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); catalogued as COSV61205381; called by muse, mutect2, varscan2
- ATP8A1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1463774048, COSV52542296; called by muse, mutect2, varscan2
- ATP9B | c.2849C>T p.S950F | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141754612; called by muse, mutect2, varscan2
- ATR | c.6329C>T p.S2110F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs751140070, COSV100638693, COSV63388642, COSV63388770; called by muse, mutect2, varscan2
- AURKA | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs1338142196, COSV57169415; called by muse, mutect2, varscan2
- AVPR1B | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868925962, COSV100899448, COSV65637750; called by muse, mutect2, varscan2
- AXDND1 | c.2613A>G p.Q871= | Splice Region (SNP) | VAF 5/21 reads (24%) | catalogued as rs1216184259, COSV62642170; called by muse, mutect2, varscan2
- B3GAT1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs376403465, COSV56994703; called by muse, mutect2, varscan2
- BBS1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.244); catalogued as rs755308059; called by muse, mutect2, varscan2
- BCL11A | c.1679C>T p.S560L (on ENST00000335712 / NM_001365609.1; = p.S594L on NM_018014.4) | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV59634074; called by muse, mutect2, varscan2
- BICD2 | c.2239C>G p.R747G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1313441, COSV63550165; called by muse, mutect2
- BIN2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57207000; called by muse, mutect2, varscan2
- BLVRA | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55515513; called by muse, mutect2, varscan2
- BMPR1B | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52779906; called by muse, mutect2, varscan2
- BPIFA3 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs1486627966, COSV64926078; called by muse, mutect2, varscan2
- BRINP3 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs1365909278, COSV66528943, COSV66533221; called by muse, mutect2, varscan2
- BTBD7 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs143914698; called by muse, mutect2, varscan2
- BZW1 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63350205; called by muse, mutect2, varscan2
- C1QTNF2 | c.307G>A p.G103R (on ENST00000393975; = p.G58R on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67433062; called by muse, mutect2, varscan2
- C2CD2 | c.597G>A p.E199= | Splice Region (SNP) | VAF 19/50 reads (38%) | catalogued as COSV61600073; called by muse, mutect2, varscan2
- C5AR1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV61893017; called by muse, mutect2, varscan2
- C6orf58 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.898); catalogued as COSV61666970; called by muse, mutect2, varscan2
- C8B | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100980766, COSV64778587; called by muse, mutect2, varscan2
- C9orf78 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59616712; called by muse, mutect2, varscan2
- CA10 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53361798; called by muse, mutect2, varscan2
- CACNA1B | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV53138440; called by muse, mutect2, varscan2
- CACNA1S | c.4141A>G p.M1381V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62941958; called by muse, mutect2, varscan2
- CACNA1S | c.1514G>A p.C505Y | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1304741009, COSV62941963; called by muse, mutect2, varscan2
- CACNA2D3 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55562927; called by muse, mutect2, varscan2
- CACNB4 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV52398824; called by muse, mutect2, varscan2
- CACNG5 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.285); catalogued as COSV50057402; called by muse, mutect2, varscan2
- CADM2 | c.178G>A p.A60T (on ENST00000407528 / NM_001167674.2; = p.A62T on NM_153184.4) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV67391086; called by muse, mutect2, varscan2
- CALN1 | c.178G>A p.E60K (on ENST00000329008 / NM_001017440.3; = p.E102K on NM_031468.4) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV61142993; called by muse, mutect2, varscan2
- CAMSAP1 | c.3302C>T p.S1101F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56725606; called by muse, mutect2, varscan2
- CANT1 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV56606181; called by muse, mutect2, varscan2
- CARD6 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV54567741; called by muse, mutect2, varscan2
- CASR | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56139583; called by muse, mutect2, varscan2
- CATSPERB | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866512933, COSV56426913; called by muse, mutect2, varscan2
- CAVIN2 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV58424997; called by muse, mutect2, varscan2
- CCDC141 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV55378318; called by muse, mutect2, varscan2
- CCDC74A | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.301); catalogued as rs145934024, COSV54605168; called by muse, mutect2, varscan2
- CCDC81 | c.1496C>T p.P499L (on ENST00000445632 / NM_001156474.2; = p.P409L on NM_021827.4) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV53580248; called by muse, mutect2, varscan2
- CCDC87 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs1565320513, COSV59579877; called by muse, mutect2, varscan2
- CCDC88C | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV66239890; called by muse, mutect2
- CCL8 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV67014125; called by muse, mutect2, varscan2
- CCNP | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs769980998, COSV55688213; called by muse, mutect2, varscan2
- CCR2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs748725992, COSV52749516; called by muse, mutect2, varscan2
- CD109 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV54653580; called by muse, mutect2, varscan2
- CD109 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1468574679, COSV54646694; called by muse, mutect2, varscan2
- CD163L1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.625); catalogued as COSV58012964; called by muse, mutect2, varscan2
- CD244 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.186); catalogued as COSV59239881; called by muse, mutect2, varscan2
- CDC40 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57011054; called by muse, mutect2, varscan2
- CDC40 | c.1646A>T p.H549L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57011072; called by muse, mutect2, varscan2
- CDCA2 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV57947468; called by muse, mutect2, varscan2
- CDCA7L | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368150780; called by muse, mutect2
- CDCP1 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV56106974; called by muse, mutect2, varscan2
- CDH12 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1211476604, COSV66420319, COSV66423634; called by muse, mutect2
- CDH18 | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV56900694, COSV56943975; called by muse, mutect2, varscan2
- CDH20 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV53014274, COSV99405132; called by muse, mutect2, varscan2
- CDH7 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs766062933, COSV59885424; called by muse, mutect2
- CEACAM5 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs782730168, COSV55753650; called by muse, mutect2, varscan2
- CELSR1 | c.7872C>T p.I2624= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as rs769638723, COSV53084031; called by muse, mutect2, varscan2
- CENPE | c.2723G>A p.R908K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1407167443, COSV54385546; called by muse, mutect2, varscan2
- CENPX | c.36G>A p.K12= | Splice Region (SNP) | VAF 6/10 reads (60%) | catalogued as rs1568011056, COSV60713021; called by mutect2, varscan2
- CES3 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV57594567; called by muse, mutect2, varscan2
- CFAP43 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1487201967, COSV53379783; called by muse, mutect2, varscan2
- CFAP54 | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1193141126, COSV61573134; called by muse, mutect2, varscan2
- CFAP77 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV58010101; called by muse, mutect2, varscan2
- CFH | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779590934, COSV66411138, COSV66411481; called by muse, mutect2, varscan2
- CFHR5 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV56825192, COSV99889681; called by muse, mutect2, varscan2
- CFHR5 | c.1571G>A p.R524K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56825212; called by muse, mutect2, varscan2
- CHKA | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV55841118; called by muse, mutect2
- CHST1 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57324789; called by muse, mutect2, varscan2
- CIB3 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV54165433; called by muse, mutect2, varscan2
- CIT | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV55876700; called by muse, mutect2, varscan2
- CKAP4 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV65172505; called by muse, mutect2, varscan2
- CKAP5 | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.521); catalogued as rs1417656184, COSV56371363; called by muse, mutect2, varscan2
- CLCA4 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55369819; called by muse, mutect2, varscan2
- CLDN1 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55044614; called by muse, mutect2, varscan2
- CLGN | c.1115G>A p.W372* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV57775752; called by muse, mutect2, varscan2
- CLPS | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1267702100, COSV99463877; called by muse, varscan2
- CLVS2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs750382549, COSV51562393, COSV51567732; called by muse, mutect2, varscan2
- CNGB1 | c.3086G>A p.G1029E | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51904158; called by muse, mutect2, varscan2
- CNTN4 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61873377; called by muse, mutect2, varscan2
- CNTN6 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.334); catalogued as COSV63165467; called by muse, mutect2
- CNTNAP1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs767466032, COSV52852607; called by muse, mutect2, varscan2
- CNTNAP2 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs372532510; called by muse, mutect2, varscan2
- COBLL1 | c.3352G>A p.E1118K (on ENST00000392717; = p.E1080K on NM_014900.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52072390; called by muse, mutect2, varscan2
- COBLL1 | c.3076C>T p.P1026S (on ENST00000392717; = p.P988S on NM_014900.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1221402579, COSV52072407; called by muse, mutect2, varscan2
- COL11A2 | c.2269G>A p.G757S (on ENST00000341947 / NM_080680.3; = p.G650S on NM_080679.2) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409401466, COSV59499916; called by muse, varscan2
- COL17A1 | c.1563G>T p.K521N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV62228286; called by muse, mutect2, varscan2
- COL18A1 | c.2846C>T p.P949L (on ENST00000359759 / NM_130444.3; = p.P714L on NM_030582.4) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV62704488; called by muse, mutect2, varscan2
- COL20A1 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745799526, COSV58922855; called by muse, mutect2
- COL4A3 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV67416903; called by muse, mutect2, varscan2
- COL4A3 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101170225, COSV67414765; called by muse, mutect2, varscan2
- COL4A5 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV60363263; called by muse, mutect2, varscan2
- COL4A5 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60357500; called by muse, mutect2, varscan2
- COL5A1 | c.4154C>T p.P1385L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1418421771, COSV65672564; called by muse, mutect2, varscan2
- COL5A2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66412247; called by muse, mutect2, varscan2
- COL5A3 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV53415728; called by muse, mutect2
- COL6A6 | c.2366A>G p.D789G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62031994; called by muse, mutect2, varscan2
- COL7A1 | c.4934C>T p.P1645L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs764468586, COSV60390788; called by muse, mutect2, varscan2
- COL9A1 | c.1730G>A p.G577E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57888618; called by muse, varscan2
- COPG1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59115624; called by muse, mutect2, varscan2
- CP | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.433); catalogued as COSV52829795; called by muse, mutect2, varscan2
- CPNE4 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1330733089, COSV70192470; called by muse, mutect2, varscan2
- CPS1 | c.584C>A p.P195Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51818136; called by muse, mutect2, varscan2
- CPXM2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV53867059; called by muse, mutect2, varscan2
- CPZ | c.1301G>A p.G434E (on ENST00000360986 / NM_001014447.3; = p.G423E on NM_003652.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59924437; called by muse, mutect2, varscan2
- CRB2 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63504513; called by muse, mutect2
- CRNKL1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV55639555; called by muse, mutect2, varscan2
- CRNKL1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs771112536, COSV55639559; called by muse, mutect2, varscan2
- CSF2RA | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62625880; called by muse, mutect2, varscan2
- CTSV | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as rs767753928, COSV99414395; called by muse, mutect2, varscan2
- CYLC1 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV61411337; called by muse, mutect2, varscan2
- CYP21A2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1312672769, COSV64484046; called by muse, mutect2, varscan2
- CYP2C8 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV64877768; called by muse, mutect2, varscan2
- CYP2F1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV58528349; called by muse, mutect2, varscan2
- CYP7B1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV59582903; called by muse, varscan2
- CYP7B1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867209693, COSV59593492; called by muse, mutect2, varscan2
- CYSLTR2 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as rs1325522802, COSV56166507; called by muse, mutect2, varscan2
- DACT1 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs201839104, COSV60022404; called by muse, mutect2, varscan2
- DBH | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV55041858, COSV99708118; called by muse, mutect2, varscan2
- DBX2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV60335902; called by muse, mutect2, varscan2
- DCC | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV71427379, COSV71437043; called by muse, mutect2, varscan2
- DCDC2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752020799, COSV65832772; called by muse, mutect2, varscan2
- DCT | c.1407G>A p.W469* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs764655568, COSV65468966; called by muse, mutect2, varscan2
- DCX | c.1090G>A p.D364N (on ENST00000636035 / NM_001195553.2; = p.D358N on NM_000555.3) | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.956); catalogued as COSV57572715; called by muse, mutect2, varscan2
- DEFB118 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV53621043; called by muse, mutect2, varscan2
- DEUP1 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV53214670; called by muse, mutect2, varscan2
- DHRS12 | c.140G>T p.G47V (on ENST00000444610 / NM_001377930.1; = p.E26* on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54472402; called by muse, mutect2, varscan2
- DIDO1 | c.5402G>A p.G1801E | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56629470; called by muse, mutect2, varscan2
- DLG4 | c.586G>A p.E196K (on ENST00000399506 / NM_001321075.3; = p.E239K on NM_001365.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV57240615; called by muse, mutect2, varscan2
- DMD | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as CD073620, CX1510001, COSV55888604; called by muse, mutect2, varscan2
- DMWD | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52180477; called by muse, mutect2, varscan2
- DMXL1 | c.4346C>T p.T1449I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs766681061, COSV60717498; called by muse, mutect2, varscan2
- DNAH10 | c.3769G>A p.E1257K (on ENST00000409039; = p.E1196K on NM_207437.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV68998090; called by muse, mutect2
- DNAH10 | c.6413T>C p.V2138A (on ENST00000409039; = p.V2077A on NM_207437.3) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1207784973, COSV68998093; called by muse, varscan2
- DNAH11 | c.6365C>T p.P2122L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780267681; called by muse, mutect2, varscan2
- DNAH17 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1568229767, COSV67758672; called by muse, mutect2, varscan2
- DNAH2 | c.5150T>C p.I1717T | Missense Mutation (SNP) | VAF 117/361 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV66723070; called by muse, mutect2, varscan2
- DNAH5 | c.11176C>T p.Q3726* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs867684159, COSV54208224; called by muse, mutect2, varscan2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by muse, mutect2, varscan2
- DNAH5 | c.5732C>T p.P1911L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV54240933; called by muse, mutect2, varscan2
- DNAH5 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV54240949; called by muse, mutect2, varscan2
- DNAH7 | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs13034775; called by muse, mutect2, varscan2
- DNAH7 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868401999, COSV56756741; called by muse, varscan2
- DNAH8 | c.8023G>A p.A2675T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV59466422; called by muse, mutect2, varscan2
- DNAH8 | c.10516C>T p.L3506F | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59466444; called by muse, mutect2, varscan2
- DNAH8 | c.13429C>T p.H4477Y | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as rs1217668162, COSV59466472; called by muse, mutect2, varscan2
- DNAJC28 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58721980; called by muse, mutect2, varscan2
- DNER | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV59171750; called by muse, mutect2, varscan2
- DNMT3B | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV52416700; called by muse, mutect2, varscan2
- DOCK6 | c.2960T>C p.V987A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53918817; called by muse, mutect2, varscan2
- DPP10 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.54); PolyPhen benign (0.188); catalogued as COSV59706252; called by muse, mutect2, varscan2
- DPPA2 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs762019608, COSV72118107; called by mutect2, varscan2
- DPYD | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.043); catalogued as rs867232786, COSV64598066; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DSC2 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as COSV51867179; called by muse, mutect2, varscan2
- DSC2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51861111; called by muse, mutect2, varscan2
- DSCAM | c.5455G>A p.E1819K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68030907; called by muse, mutect2, varscan2
- DSG3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV57128203; called by muse, mutect2, varscan2
- DSG4 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57392377; called by muse, mutect2, varscan2
- DUOX2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs777734937, COSV66533097; called by muse, mutect2, varscan2
- DZIP1 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV61264949; called by muse, mutect2, varscan2
- ECE1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51664673; called by muse, mutect2, varscan2
- EFR3A | c.1714A>G p.I572V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as rs1187981307, COSV54460156; called by muse, mutect2, varscan2
- EGFR | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51783517, COSV51839766; called by muse, mutect2, varscan2
- ELK4 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs1175980684, COSV56985709; called by muse, mutect2, varscan2
- EMB | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753863851, COSV57483473; called by muse, mutect2, varscan2
- ENPP1 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV62934561; called by muse, mutect2, varscan2
- ENPP4 | c.486A>T p.E162D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.958); catalogued as COSV58089631; called by muse, mutect2, varscan2
- ENPP6 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.309); catalogued as COSV57070275; called by muse, mutect2, varscan2
- ENTHD1 | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV57322936; called by muse, mutect2, varscan2
- EPB41L4A | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54875697; called by muse, mutect2, varscan2
- EPHA8 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV51280401; called by muse, mutect2, varscan2
- EPHB1 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67666703; called by muse, mutect2
- ERC2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55645275; called by muse, mutect2
- ERICH3 | c.1605A>T p.K535N | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58613260; called by muse, mutect2, varscan2
- EVPL | c.3937G>A p.V1313M | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV56913717; called by muse, mutect2, varscan2
- EXD2 | c.1345G>A p.D449N (on ENST00000312994 / NM_001193362.1; = p.D324N on NM_018199.3) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV57281076; called by muse, mutect2
- EXOSC5 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762295191, COSV54198631; called by muse, mutect2, varscan2
- EYA2 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.85); catalogued as COSV57947767; called by muse, mutect2, varscan2
- EYA4 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.535); catalogued as COSV62057553; called by muse, varscan2
- EYA4 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV62057563; called by muse, varscan2
- FAM169A | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65846063, COSV65846948; called by muse, mutect2, varscan2
- FAM47A | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs752456861, COSV60498629; called by muse, mutect2, varscan2
- FAM83B | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60924694; called by muse, mutect2, varscan2
- FAM83B | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as rs776649451, COSV60922779; called by muse, mutect2, varscan2
- FAT2 | c.8491C>T p.Q2831* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV55825403; called by muse, mutect2, varscan2
- FAT3 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 192/681 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53098408, COSV53147794; called by muse, mutect2, varscan2
- FAT4 | c.10088T>G p.L3363R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58689576; called by muse, mutect2, varscan2
- FAT4 | c.13789G>A p.E4597K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1347852459, COSV58689889; called by muse, mutect2, varscan2
- FBXO38 | c.3396C>G p.I1132M (on ENST00000340253 / NM_205836.3; = p.I1057M on NM_030793.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs767493732, COSV57029755; called by muse, mutect2, varscan2
- FCRL1 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs764553423, COSV63824217, COSV63825106, COSV63826906; called by muse, mutect2, varscan2
- FDXR | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777828005, COSV99502045; called by muse, mutect2, varscan2
- FER1L6 | c.2439C>A p.H813Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV67551700; called by muse, mutect2, varscan2
- FGA | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398688; called by muse, mutect2, varscan2
- FGD1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as COSV64309015; called by muse, mutect2, varscan2
- FGF23 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52977183; called by muse, mutect2, varscan2
- FLG2 | c.3385G>A p.G1129R | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV66171057; called by muse, mutect2, varscan2
- FLG2 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as rs763526275, COSV66171060; called by muse, mutect2, varscan2
- FNBP4 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55448706; called by muse, mutect2, varscan2
- FOXH1 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1287757787, COSV56762146; called by muse, mutect2, varscan2
- FPR3 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59331081; called by muse, mutect2, varscan2
- FRK | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199509116, COSV73384124; called by muse, mutect2, varscan2
- FRMPD2 | c.2109G>A p.M703I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV59721232; called by muse, mutect2, varscan2
- FSCN3 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV50001672; called by muse, mutect2, varscan2
- FSIP2 | c.16687G>A p.E5563K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV58086882; called by muse, mutect2, varscan2
- FSTL4 | c.1991G>A p.S664N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV54779285; called by muse, mutect2
- FUT9 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs146949446; called by muse, mutect2, varscan2
- GABRA1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50102622; called by muse, mutect2, varscan2
- GALNT14 | c.1505G>A p.W502* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV61108641; called by muse, mutect2, varscan2
- GALNT15 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.388); catalogued as COSV60218502; called by muse, mutect2, varscan2
- GALNTL5 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67180744; called by muse, mutect2, varscan2
- GBX2 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV60445589; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV61322201; called by muse, mutect2, varscan2
- GFRAL | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100475487, COSV100475585; called by muse, mutect2, varscan2
- GGT7 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60541854; called by muse, mutect2, varscan2
- GK2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1417995112, COSV62626181; called by muse, mutect2, varscan2
- GLI2 | c.234T>A p.H78Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV58047206; called by muse, mutect2, varscan2
- GLI2 | c.3124G>A p.D1042N (on ENST00000361492 / NM_001374353.1; = p.D1059N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs762818312, COSV58038867; called by muse, mutect2, varscan2
- GML | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55277086, COSV55277879; called by muse, mutect2, varscan2
- GNA14 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV59026781; called by muse, mutect2, varscan2
- GPC6 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65524353; called by muse, mutect2, varscan2
- GPD1 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV56548708; called by muse, mutect2, varscan2
- GRIA2 | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | catalogued as COSV52398939; called by muse, mutect2, varscan2
- GRIN2A | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs933322445, CM138253; called by muse, mutect2, varscan2
- GSTA1 | c.462C>G p.S154R | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58014890, COSV58016231; called by muse, mutect2, varscan2
- GTSE1 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs201142261; called by muse, mutect2, varscan2
- H1-6 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1384996067, COSV58091036; called by muse, mutect2, varscan2
- H2BC3 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs1212342410, COSV63551297; called by muse, mutect2, varscan2
- HBS1L | c.1849A>T p.I617F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV63202130; called by muse, mutect2, varscan2
- HDAC9 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs1485280896, COSV67769001; called by muse, mutect2, varscan2
- HELZ2 | c.6808C>T p.R2270W (on ENST00000467148 / NM_001037335.2; = p.R1701W on NM_033405.3) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs201218245, COSV64443591; called by muse, mutect2, varscan2
- HEPACAM2 | c.127G>A p.G43S (on ENST00000394468 / NM_001039372.4; = p.G31S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59062216; called by muse, mutect2, varscan2
- HFE | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs747739169, CM033969, COSV58513649; called by muse, mutect2, varscan2
- HIKESHI | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as rs11539213, COSV53575121; called by muse, mutect2, varscan2
- HIVEP1 | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV65103683; called by mutect2, varscan2
- HLA-B | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as rs41557013, COSV69522241; called by muse, varscan2
- HLA-DRA | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66622953; called by muse, mutect2, varscan2
- HLA-G | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64406348; called by muse, mutect2, varscan2
- HM13 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59438346; called by muse, mutect2, varscan2
- HORMAD2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1394806064, COSV60899808; called by muse, mutect2
- HOXD13 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66832751; called by muse, mutect2, varscan2
- HS1BP3 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV58314035; called by muse, mutect2, varscan2
- HTR2A | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV101096581, COSV66327917; called by muse, mutect2, varscan2
- HYDIN | c.10282C>T p.H3428Y | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1489829567, COSV101158646; called by muse, mutect2, varscan2
- HYDIN | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.423); catalogued as rs772292636, COSV55482580, COSV55500793; called by muse, mutect2, varscan2
- IARS2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56962095; called by muse, mutect2, varscan2
- ICE2 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55033002; called by muse, mutect2, varscan2
- IGF2BP1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs1364176184, COSV51731262; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs759399751; called by muse, mutect2, varscan2
- IGHV3-15 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs781801365; called by muse, mutect2, varscan2
- IGHV3-23 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.603); catalogued as rs1555466943; called by muse, mutect2, varscan2
- IL12RB1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV59098362; called by muse, mutect2, varscan2
- IL17RC | c.958C>T p.R320W (on ENST00000295981 / NM_153461.4; = p.R234W on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs567325482, COSV55974220; called by muse, mutect2, varscan2
- IL18RAP | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs149244380; called by muse, mutect2, varscan2
- IL2RB | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV53427664; called by muse, mutect2, varscan2
- IL36B | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV52084562; called by muse, mutect2, varscan2
- INMT | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50002006; called by muse, mutect2, varscan2
- INPP5D | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1009089546, COSV64038842; called by mutect2, varscan2
- INPP5D | c.2701C>T p.P901S (on ENST00000445964 / NM_001017915.3; = p.P900S on NM_005541.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV64038845; called by muse, mutect2
- INPPL1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV53357670; called by muse, mutect2, varscan2
- INPPL1 | c.2180T>C p.V727A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV53357679; called by muse, mutect2, varscan2
- INSYN1 | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65837664; called by muse, mutect2, varscan2
- INTS2 | c.3530G>A p.G1177E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV52004722; called by muse, mutect2, varscan2
- INTU | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV58873435; called by muse, mutect2, varscan2
- IRF7 | c.1192G>A p.G398S (on ENST00000397566; = p.G385S on NM_001572.5) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs750448993, COSV52759485; called by muse, mutect2
- ITGB8 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as COSV56011827; called by muse, mutect2, varscan2
- ITK | c.1230G>A p.M410I | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV70064142; called by muse, mutect2, varscan2
- JCAD | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV64760875; called by muse, mutect2, varscan2
- JPH1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs780428213, COSV60610791; called by muse, mutect2, varscan2
- KBTBD2 | c.1697A>T p.H566L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV58363963; called by muse, mutect2, varscan2
- KCNC2 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54367411; called by muse, mutect2, varscan2
- KCND2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58577018; called by muse, mutect2, varscan2
- KCNH2 | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as CM150040, COSV51212781; called by muse, mutect2
- KCNH2 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV51212944; called by muse, mutect2, varscan2
- KCNH5 | c.1539G>A p.W513* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV59769197; called by muse, mutect2, varscan2
- KCNH6 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59005895; called by muse, mutect2, varscan2
- KCNH7 | c.1391T>A p.I464K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100034810, COSV59806047; called by muse, mutect2, varscan2
- KCNIP4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV66257984; called by muse, mutect2, varscan2
- KCNJ3 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV54531931; called by muse, mutect2, varscan2
- KCNJ5 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV57968728; called by muse, mutect2, varscan2
- KCNJ5 | c.1030T>C p.Y344H | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV57968740; called by muse, mutect2, varscan2
- KCNT2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1452776560, COSV54065701; called by muse, mutect2, varscan2
- KDM8 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV53730953; called by muse, mutect2, varscan2
- KIAA1217 | c.1360A>C p.K454Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56820207; called by muse, mutect2, varscan2
- KIF19 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV63429628; called by muse, mutect2, varscan2
- KIF1A | c.3310C>T p.P1104S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57495858; called by muse, mutect2
- KL | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66309486; called by muse, mutect2, varscan2
- KLHL12 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs777812307, COSV66127722; called by muse, mutect2, varscan2
- KLRB1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144231382, COSV99037916, COSV99987382; called by muse, mutect2, varscan2
- KMT2D | c.13399C>T p.L4467F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56467026; called by muse, mutect2, varscan2
- KPNA3 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 34/103 reads (33%) | catalogued as COSV55506085; called by muse, mutect2, varscan2
- KRT1 | c.1205A>T p.N402I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52868159; called by muse, mutect2, varscan2
- KRT17 | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60861487; called by muse, mutect2
- KRT76 | c.608T>A p.F203Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772065201, COSV60121277; called by muse, mutect2, varscan2
- KRT83 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV53340048, COSV53341448; called by muse, mutect2, varscan2
- KRTAP4-2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs1210550873, COSV66658342; called by muse, mutect2, varscan2
- KYNU | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs1372767383, COSV51588222; called by muse, mutect2
- L3MBTL3 | c.197T>A p.V66E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as COSV62387630; called by muse, mutect2, varscan2
- L3MBTL4 | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99529867; called by muse, mutect2, varscan2
- LAMA5 | c.6290C>T p.P2097L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV53366161; called by muse, varscan2
- LAMB1 | c.5297G>A p.G1766E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52738972, COSV99226932; called by muse, mutect2, varscan2
- LAMC1 | c.1144T>G p.C382G | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51157278; called by muse, mutect2, varscan2
- LARGE2 | c.369G>A p.R123= | Splice Region (SNP) | VAF 18/44 reads (41%) | catalogued as COSV57684298; called by muse, mutect2, varscan2
- LARP1B | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV52800687; called by muse, mutect2, varscan2
- LGMN | c.695G>A p.W232* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs1324401726; called by muse, mutect2, varscan2
- LNX1 | c.1594G>A p.D532N (on ENST00000263925 / NM_001126328.3; = p.D436N on NM_032622.2) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as COSV55789197, COSV99820395; called by muse, mutect2, varscan2
- LONRF2 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV66541007; called by muse, mutect2, varscan2
- LONRF3 | c.1489C>T p.H497Y (on ENST00000371628 / NM_001031855.3; = p.H456Y on NM_024778.5) | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV59149596, COSV59155136; called by muse, mutect2, varscan2
- LOXL3 | c.1167G>C p.K389N | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV51210316; called by muse, mutect2, varscan2
- LPA | c.4169G>A p.R1390Q | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs201730323, COSV60306578; called by muse, mutect2, varscan2
- LRBA | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.01); catalogued as COSV63960245; called by muse, mutect2, varscan2
- LRP1B | c.4054A>T p.I1352L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV67252090; called by muse, mutect2, varscan2
- LRRC7 | c.3592G>C p.V1198L (on ENST00000651989 / NM_001370785.2; = p.V1165L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.116); catalogued as COSV50529572; called by muse, mutect2, varscan2
- LRRTM3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV63666111; called by muse, mutect2, varscan2
- LTBP1 | c.3322G>A p.G1108R (on ENST00000404816 / NM_206943.4; = p.G782R on NM_000627.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55382799; called by muse, mutect2, varscan2
- LTN1 | c.4970C>T p.P1657L | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63734643; called by muse, mutect2, varscan2
- LUZP2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1215809915, COSV100420969, COSV61199599; called by muse, mutect2, varscan2
- LY9 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372951907, COSV54434246; called by muse, mutect2, varscan2
- MAB21L2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV58261462; called by muse, mutect2, varscan2
- MACC1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.054); catalogued as COSV60544885; called by muse, mutect2, varscan2
- MAEL | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV63305770; called by muse, mutect2, varscan2
- MAGEA12 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1556833673, COSV63295124; called by muse, mutect2, varscan2
- MAGEC3 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV68924034; called by muse, varscan2
- MAGEE2 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs757100041, COSV64897913; called by muse, mutect2, varscan2
- MAP3K11 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV58420941; called by muse, mutect2, varscan2
- MAP3K12 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57234644; called by muse, mutect2, varscan2
- MAP3K4 | c.2939A>G p.Q980R | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV62336290; called by muse, mutect2, varscan2
- MAP3K5 | c.3737G>A p.G1246E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV62887821; called by muse, mutect2, varscan2
- MAP3K9 | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV67122265; called by muse, mutect2, varscan2
- MAPK4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200603915; called by muse, mutect2, varscan2
- MARK2 | c.1459C>T p.P487S (on ENST00000402010 / NM_001039469.2; = p.P486S on NM_004954.5) | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.035); catalogued as COSV59286418; called by muse, mutect2, varscan2
- MARVELD2 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57781584; called by muse, mutect2, varscan2
- MATK | c.1270C>T p.P424S (on ENST00000310132 / NM_139355.3; = p.P425S on NM_002378.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59555440; called by muse, mutect2, varscan2
- MCAM | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV50649239; called by muse, mutect2, varscan2
- MCTP1 | c.2508G>A p.W836* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56526205; called by muse, mutect2, varscan2
- MDGA2 | c.1114G>A p.D372N (on ENST00000399232 / NM_001113498.2; = p.D74N on NM_182830.4) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.549); catalogued as COSV62104787; called by muse, mutect2, varscan2
- MECR | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV55286715; called by muse, mutect2, varscan2
- MEFV | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); catalogued as rs104895110, CM041800, COSV54826976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEP1A | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs1366124403, COSV57921621; called by muse, mutect2, varscan2
- MEP1A | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV57921630; called by muse, mutect2, varscan2
- MERTK | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as COSV54932934; called by muse, mutect2, varscan2
- MFSD6L | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs772812130, COSV61004486; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MICAL1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV62193184; called by muse, mutect2, varscan2
- MICAL3 | c.4946C>A p.S1649Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.08); catalogued as COSV71588789; called by muse, mutect2, varscan2
- MICOS10 | c.128T>C p.L43S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV59554598; called by muse, mutect2, varscan2
- MME | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559963546, COSV64709094, COSV64711049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP27 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV52781883; called by muse, mutect2, varscan2
- MMRN1 | c.1616G>A p.S539N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53336234, COSV53340512; called by muse, mutect2, varscan2
- MOGAT1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV71479986; called by muse, mutect2, varscan2
- MORC1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51726030; called by muse, mutect2, varscan2
- MPC2 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs17343090, COSV54797345; called by muse, mutect2, varscan2
- MRO | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV56497440; called by muse, mutect2, varscan2
- MRTFB | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57959904; called by muse, mutect2, varscan2
- MSH4 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs267598724; called by muse, mutect2, varscan2
- MTUS2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV70918933; called by muse, mutect2, varscan2
- MUC16 | c.38650G>A p.E12884K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as COSV67454159; called by muse, mutect2, varscan2
- MUC16 | c.26222C>T p.S8741F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.412); catalogued as rs754799066, COSV67480687; called by muse, mutect2, varscan2
- MUC16 | c.23483C>T p.S7828F | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.358); catalogued as rs866144451, COSV67455901, COSV67480691; called by muse, mutect2, varscan2
- MUC16 | c.15262G>A p.E5088K | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV67480695; called by muse, mutect2, varscan2
- MUC16 | c.5665G>A p.G1889R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67480702; called by muse, mutect2, varscan2
- MUC16 | c.3034A>G p.T1012A | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67480705; called by muse, mutect2, varscan2
- MYH2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55433645; called by muse, mutect2, varscan2
- MYH2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs578188627, COSV55443758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV55441984, COSV55443765; called by muse, mutect2, varscan2
- MYH7B | c.5854G>A p.D1952N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.159); catalogued as COSV52678679; called by muse, mutect2, varscan2
- MYLK2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV65658857; called by muse, mutect2, varscan2
- MYO1H | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60448634; called by muse, mutect2, varscan2
- MYOM2 | c.3284G>A p.G1095E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50741858; called by muse, mutect2, varscan2
- MYT1L | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs757649588, COSV67717585; called by muse, mutect2, varscan2
- NACA2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1388775574, COSV71713114, COSV71713117; called by muse, varscan2
- NBEA | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV59805786; called by muse, mutect2
- NBPF20 | c.16748C>T p.S5583L (on ENST00000369373; = p.S5144L on NM_001278267.1) | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs782739503, COSV65009828; called by muse, mutect2, varscan2
- NDST1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV55789214; called by muse, mutect2, varscan2
- NDUFAF2 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54015971, COSV54017109; called by muse, mutect2, varscan2
- NECTIN2 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52978821; called by muse, mutect2, varscan2
- NEDD4L | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.219); catalogued as COSV56849370; called by muse, mutect2, varscan2
- NF1 | c.3340T>A p.L1114M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.829); catalogued as COSV62212302; called by muse, mutect2, varscan2
- NFS1 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766586663, COSV58293445; called by muse, mutect2, varscan2
- NLGN4Y | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV59298433; called by muse, mutect2, varscan2
- NLRP10 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV60781402; called by muse, mutect2, varscan2
- NLRP11 | c.1940G>A p.G647D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867936776, COSV64088290; called by muse, mutect2, varscan2
- NLRP4 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV56716391; called by muse, mutect2, varscan2
- NLRP7 | c.2041G>A p.E681K (on ENST00000340844 / NM_206828.3; = p.E653K on NM_139176.3) | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV60178352; called by muse, varscan2
- NLRP8 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV52591112; called by muse, mutect2, varscan2
- NLRP9 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV60463477; called by muse, mutect2, varscan2
- NMT1 | c.1348T>C p.F450L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51961339; called by muse, mutect2, varscan2
- NNMT | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55474468; called by muse, mutect2, varscan2
- NOBOX | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV56196257; called by muse, mutect2, varscan2
- NOD1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.352); catalogued as COSV56113848; called by muse, mutect2, varscan2
- NOTCH4 | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV66682619; called by muse, mutect2, varscan2
- NOX3 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50158116; called by muse, mutect2, varscan2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2, varscan2
- NPAP1 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.537); catalogued as COSV61509128; called by muse, mutect2, varscan2
- NPAS4 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV60650228, COSV60651747; called by muse, mutect2, varscan2
- NPC1L1 | c.3121G>A p.D1041N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV56928208; called by muse, mutect2, varscan2
- NPSR1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV100706287, COSV62205008; called by muse, mutect2
- NPY2R | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as COSV61529016; called by muse, mutect2, varscan2
- NRXN1 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58475158; called by muse, mutect2, varscan2
- NRXN2 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs1259804240, COSV55459310; called by muse, mutect2, varscan2
- NT5C1B | c.767C>T p.S256F (on ENST00000359846 / NM_001199086.2; = p.S196F on NM_033253.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV58397716; called by muse, varscan2
- NT5C1B | c.685G>A p.D229N (on ENST00000359846 / NM_001199086.2; = p.D169N on NM_033253.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV58397723; called by muse, varscan2
- NUP214 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63911572; called by muse, mutect2, varscan2
- NWD1 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs1261391509; called by muse, mutect2
- NWD1 | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs866682805, COSV60338490; called by muse, mutect2, varscan2
- NXPH1 | c.750A>T p.K250N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68317630; called by muse, mutect2, varscan2
- OPRK1 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV55568737; called by muse, mutect2, varscan2
- OPRK1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55572495; called by muse, mutect2, varscan2
- OPRPN | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.041); catalogued as COSV68192627; called by muse, mutect2, varscan2
- OR11H12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1370242111, COSV73569293; called by muse, mutect2, varscan2
- OR13C4 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs778485448, COSV52925917; called by muse, mutect2, varscan2
- OR13C5 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866884938, COSV101053045, COSV66164263; called by muse, mutect2, varscan2
- OR13G1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62944846; called by muse, mutect2, varscan2
- OR13G1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV62943365; called by muse, mutect2, varscan2
- OR1L6 | c.346C>T p.P116S (on ENST00000373684; = p.P80S on NM_001004453.2) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59029163; called by muse, mutect2, varscan2
- OR2B2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV57580264; called by muse, mutect2, varscan2
- OR2C1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV59240770; called by muse, mutect2, varscan2
- OR2D3 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs755638690, COSV58573418; called by muse, mutect2, varscan2
- OR2G3 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100180795, COSV60680774; called by muse, mutect2, varscan2
- OR2M5 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs150844237, COSV63546597; called by muse, varscan2
- OR2M5 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1208396477, COSV63546718; called by muse, varscan2
- OR3A2 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs868588159, COSV68695172; called by muse, mutect2, varscan2
- OR4A16 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59044415; called by muse, mutect2, varscan2
- OR4C11 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as rs775788723, COSV56354349; called by muse, mutect2, varscan2
- OR4C13 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV73648603, COSV73648757; called by muse, mutect2, varscan2
- OR4D2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73459710; called by muse, mutect2, varscan2
- OR4D9 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61434524; called by muse, mutect2, varscan2
- OR4K1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53461408; called by muse, mutect2, varscan2
- OR4K13 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59860237; called by muse, mutect2, varscan2
- OR4K2 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1341900554, COSV53850773; called by muse, mutect2, varscan2
- OR4Q3 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV100056748; called by muse, mutect2, varscan2
- OR4X2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166747967, COSV56582293; called by muse, varscan2
- OR4X2 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56582840; called by muse, varscan2
- OR51E2 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1207448763, COSV67807399; called by muse, mutect2, varscan2
- OR51M1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs765764808, COSV60785087; called by muse, mutect2, varscan2
- OR5H1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV63402990, COSV99075120; called by muse, mutect2, varscan2
- OR5H6 | c.235C>T p.L79F (on ENST00000642105; = p.L63F on NM_001005479.2) | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101051799, COSV67351865; called by muse, mutect2, varscan2
- OR6B1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.477); catalogued as rs1217664623, COSV68770427; called by muse, mutect2, varscan2
- OR6C3 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV65570564, COSV65571575; called by muse, varscan2
- OR6C3 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV65571595; called by muse, mutect2, varscan2
- OR6C75 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV58551624, COSV58553074; called by muse, mutect2, varscan2
- OR6Y1 | c.401C>G p.P134R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56930466; called by muse, mutect2, varscan2
- OR7D2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1347866764, COSV60140672; called by muse, mutect2, varscan2
- OR8D4 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV58430058; called by muse, mutect2, varscan2
- OTOF | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV55511312, COSV99717524; called by muse, mutect2, varscan2
- OTOR | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV55722193; called by muse, mutect2
- P4HA3 | c.1169G>A p.S390N | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59042987; called by muse, mutect2, varscan2
- PADI3 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1219322057, COSV64934934; called by muse, varscan2
- PAK3 | c.428C>T p.S143F (on ENST00000262836 / NM_001324328.2; = p.S128F on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV53276458; called by muse, mutect2, varscan2
- PAN2 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.541); catalogued as rs754158169, COSV57755123; called by muse, mutect2, varscan2
- PBRM1 | c.2149A>T p.K717* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV56291092; called by muse, mutect2, varscan2
- PBRM1 | c.1819-1G>A p.X607_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV56259114; called by muse, mutect2
- PCARE | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV59056414; called by muse, mutect2, varscan2
- PCDH1 | c.2881G>A p.G961S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.951); catalogued as COSV54617182; called by muse, mutect2, varscan2
- PCDH11Y | c.3983C>T p.S1328F | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV53086611; called by muse, mutect2, varscan2
- PCDH15 | c.5455C>T p.P1819S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs765316016, COSV100228780, COSV57357068; called by muse, mutect2
- PCDH18 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV61266449; called by muse, mutect2, varscan2
- PCDH18 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV61266439; called by muse, mutect2, varscan2
- PCDHA11 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56480358, COSV56484098; called by muse, mutect2, varscan2
- PCDHA2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.147); catalogued as rs17844246, COSV65366110; called by muse, mutect2, varscan2
- PCDHA5 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV65353977; called by muse, mutect2, varscan2
- PCDHB3 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.082); catalogued as COSV50587235; called by muse, mutect2, varscan2
- PCDHB3 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.886); catalogued as rs17844390, COSV50600614; called by muse, mutect2, varscan2
- PCDHB3 | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50600716; called by muse, mutect2, varscan2
- PCDHB8 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.16); catalogued as COSV50753714; called by muse, mutect2, varscan2
- PCDHGA1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs201338329, COSV65298095; called by muse, mutect2, varscan2
- PCLO | c.11159T>G p.V3720G | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV61652286; called by muse, mutect2, varscan2
- PCLO | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.434); catalogued as rs866533946, COSV61625352; called by muse, mutect2, varscan2
- PCSK5 | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); catalogued as COSV65093129; called by muse, mutect2, varscan2
- PDLIM5 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58750595; called by muse, mutect2, varscan2
- PDP2 | c.939C>G p.N313K | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61241183; called by muse, mutect2, varscan2
- PFKL | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV62464556; called by muse, mutect2, varscan2
- PGBD5 | c.1135C>G p.L379V (on ENST00000525115; = p.L448V on NM_001258311.2) | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58412767; called by muse, mutect2, varscan2
- PGLYRP3 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51950132, COSV51951620; called by muse, varscan2
- PGLYRP3 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51951636; called by muse, varscan2
- PGLYRP3 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV51951654, COSV99320034; called by muse, mutect2, varscan2
- PHGDH | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 420/1634 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV65571787; called by muse, varscan2
- PHOX2B | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as COSV99891658; called by muse, mutect2, varscan2
- PIEZO2 | c.7762C>T p.P2588S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53292127; called by muse, mutect2, varscan2
- PIK3CG | c.2137T>C p.F713L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV63251212; called by muse, mutect2, varscan2
- PIK3R6 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs1365659399, COSV61004491; called by muse, mutect2
- PKD1 | c.8210C>T p.S2737L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs773182267, COSV51921383, COSV99237111; called by muse, mutect2, varscan2
- PLA2G3 | c.185G>A p.W62* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV53211253; called by muse, mutect2, varscan2
- PLCL2 | c.1252G>A p.D418N (on ENST00000615277 / NM_001144382.2; = p.D292N on NM_015184.5) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1394343507, COSV67623893; called by muse, varscan2
- PLCL2 | c.1300C>T p.H434Y (on ENST00000615277 / NM_001144382.2; = p.H308Y on NM_015184.5) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67623894, COSV67623985; called by muse, varscan2
- PLCL2 | c.1756G>A p.E586K (on ENST00000615277 / NM_001144382.2; = p.E460K on NM_015184.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV67620530; called by muse, mutect2, varscan2
- PLCXD3 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV60613671; called by muse, mutect2, varscan2
- PLEKHA6 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV55337559; called by muse, mutect2, varscan2
- PLG | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV51984799; called by muse, mutect2, varscan2
- PLPP3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV64838687; called by muse, mutect2, varscan2
- PLXDC1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs918117295, COSV59549440, COSV59549628; called by muse, mutect2, varscan2
- PMFBP1 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV52820040; called by muse, mutect2
- PNLDC1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs759936192, COSV51706002; called by muse, mutect2, varscan2
- PNN | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as COSV53766587; called by muse, mutect2
- POLL | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV54576720; called by muse, mutect2, varscan2
- POM121 | c.3236C>T p.T1079I (on ENST00000434423; = p.T814I on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57520664; called by muse, mutect2, varscan2
- POPDC2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377607045, COSV51739912; called by muse, mutect2, varscan2
- POTEE | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58237822; called by muse, mutect2, varscan2
- PPFIA2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV61044442; called by muse, mutect2
- PPP1R13L | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as rs141349857; called by muse, mutect2, varscan2
- PPP1R3A | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs267601239, COSV52888188; called by muse, mutect2, varscan2
- PPP4R4 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58556641; called by muse, mutect2, varscan2
- PRAMEF1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV60013436; called by muse, mutect2, varscan2
- PRAMEF2 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs181155957, COSV53572920; called by muse, mutect2, varscan2
- PRB1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 87/477 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV53705190; called by muse, mutect2, varscan2
- PRB4 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV54398595; called by muse, mutect2, varscan2
- PRDM1 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV64845473; called by muse, mutect2, varscan2
- PRDM9 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57010376, COSV57010765; called by muse, mutect2, varscan2
- PRIMA1 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60263804; called by muse, mutect2, varscan2
- PRIMPOL | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV59249772; called by muse, mutect2, varscan2
- PRKDC | c.7724C>T p.P2575L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1234764397, COSV58058986, COSV58064993; called by muse, mutect2, varscan2
- PROSER1 | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as COSV61488812; called by muse, mutect2, varscan2
- PRRC2B | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV61942555; called by muse, mutect2, varscan2
- PRRG3 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64851335; called by muse, mutect2, varscan2
- PRSS35 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs532622580, COSV63800962; called by muse, mutect2, varscan2
- PRSS38 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV64541099; called by muse, mutect2, varscan2
- PSG5 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as rs146386413; called by muse, varscan2
- PSG5 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs775366471, COSV61654043; called by muse, varscan2
- PTH | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs762100011, COSV56378739; called by muse, mutect2, varscan2
- PTPN5 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.157); catalogued as COSV62127507; called by muse, varscan2
- PTPRD | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs966706082, COSV61928983; called by muse, mutect2, varscan2
- PTPRD | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61959522; called by muse, mutect2, varscan2
- PTPRF | c.4921C>T p.L1641F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63447076; called by muse, mutect2, varscan2
- PTPRK | c.2363G>A p.G788E (on ENST00000368215 / NM_001291984.2; = p.G789E on NM_002844.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.186); catalogued as COSV63903241; called by muse, mutect2, varscan2
- PTPRT | c.3538C>T p.Q1180* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV61969777, COSV62000873, COSV62028893; called by muse, varscan2
- RAD17 | c.1889del p.G630Vfs*16 (on ENST00000380774 / NM_133339.2; = p.G619Vfs*16 on NM_002873.1) | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as COSV51458695; called by mutect2, pindel, varscan2
- RANGAP1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV62364199; called by muse, mutect2, varscan2
- RBSN | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV53794633; called by muse, mutect2, varscan2
- RCN3 | c.792T>G p.S264R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs777910730, COSV54543070; called by muse, mutect2
- RDH16 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV62458182; called by muse, mutect2, varscan2
- REXO5 | c.2125-1G>A p.X709_splice | Splice Site (SNP) | VAF 52/174 reads (30%) | catalogued as COSV54473671; called by muse, mutect2, varscan2
- RFPL3 | c.599C>T p.S200F (on ENST00000249007 / NM_001098535.1; = p.S171F on NM_006604.2) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50751105; called by muse, mutect2, varscan2
- RFPL4B | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769985727, COSV101480733, COSV71437071; called by muse, mutect2, varscan2
- RHD | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.309); catalogued as COSV59646854; called by muse, mutect2, varscan2
- RIMS1 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV53470837; called by muse, mutect2, varscan2
- RIMS2 | c.4273C>T p.P1425S (on ENST00000666250 / NM_001348490.2; = p.P996S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51703688; called by muse, mutect2, varscan2
- RNF17 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV55046399; called by muse, mutect2, varscan2
- RNF180 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV56963838; called by muse, mutect2, varscan2
- RP1L1 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as COSV66758045; called by muse, mutect2, varscan2
- RPGRIP1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV52853781; called by muse, mutect2, varscan2
- RPH3A | c.1566G>A p.M522I (on ENST00000389385 / NM_001143854.2; = p.M518I on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV66990283; called by muse, varscan2
- RSPO2 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52650583; called by muse, mutect2, varscan2
- RXFP1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351663425, COSV57047463, COSV57052819; called by muse, mutect2, varscan2
- RYR1 | c.9688C>T p.L3230= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as COSV62104276; called by muse, mutect2
- RYR3 | c.7993G>A p.E2665K (on ENST00000389232; = p.E2666K on NM_001036.6) | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV66801707; called by muse, mutect2, varscan2
- SACS | c.13048G>A p.E4350K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as CM1311614, COSV66544229; called by muse, mutect2, varscan2
- SALL2 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV58104850; called by muse, mutect2, varscan2
- SAMD3 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV60774959, COSV60775188; called by muse, mutect2, varscan2
- SAMD9 | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV66076800; called by muse, mutect2, varscan2
- SCAF8 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV63200293; called by muse, mutect2, varscan2
- SCD5 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56727949; called by muse, mutect2, varscan2
- SCN10A | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71860773, COSV71861985; called by muse, varscan2
- SCN11A | c.4403C>T p.A1468V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV56574451; called by muse, mutect2, varscan2
- SCN1A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs769582667, COSV57660030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN2A | c.5422G>A p.D1808N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs767541516, COSV51849495; called by muse, mutect2, varscan2
- SCN3A | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs749133387, COSV51817823; called by muse, mutect2, varscan2
- SDSL | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV61885020; called by muse, mutect2, varscan2
- SEC14L3 | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV53180705; called by muse, mutect2, varscan2
- SEC62 | c.835A>G p.R279G | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as COSV61261788; called by muse, mutect2, varscan2
- SEMA3F | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265939085, COSV50029511; called by mutect2, varscan2
- SEMG2 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.999); catalogued as rs1345550444, COSV65647459; called by muse, mutect2, varscan2
- SERPINA10 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV56227479; called by muse, mutect2, varscan2
- SERPINB11 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV66957454; called by muse, mutect2, varscan2
- SEZ6 | c.2198T>A p.V733E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV57983092; called by muse, mutect2, varscan2
- SGSM1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.565); catalogued as COSV101241167, COSV68512093; called by muse, mutect2, varscan2
- SH3TC1 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs371546678; called by muse, mutect2, varscan2
- SHANK3 | c.1028T>C p.V343A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53189171; called by muse, mutect2, varscan2
- SIPA1L1 | c.3413C>T p.S1138F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62172131; called by muse, mutect2, varscan2
- SIRPB1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53539927; called by muse, mutect2, varscan2
- SKAP1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.835); catalogued as COSV61149614; called by muse, mutect2, varscan2
- SLAMF7 | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV63563245, COSV63563742; called by muse, mutect2, varscan2
- SLC17A1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55080076, COSV99765680; called by muse, mutect2, varscan2
- SLC17A5 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV63288056; called by muse, mutect2, varscan2
- SLC1A6 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV55672326, COSV55675353; called by muse, mutect2, varscan2
- SLC26A3 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60641493; called by muse, mutect2, varscan2
- SLC27A1 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53099229; called by muse, mutect2, varscan2
- SLC35F4 | c.274G>A p.G92S (on ENST00000339762 / NM_001352015.2; = p.G56S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV60266032; called by muse, mutect2, varscan2
- SLC38A4 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs764640245, COSV56969554; called by muse, mutect2, varscan2
- SLC4A1 | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776130740, COSV52261824; called by muse, mutect2, varscan2
- SLC4A9 | c.347G>A p.W116* (on ENST00000507527 / NM_001258428.2; = p.W92* on NM_031467.3) | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV50200873; called by muse, mutect2, varscan2
- SLC7A13 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.42); catalogued as COSV52536021; called by muse, mutect2, varscan2
- SLC8A3 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV63524509; called by muse, mutect2, varscan2
- SLCO4C1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs138439271; called by muse, mutect2, varscan2
- SLITRK1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV65675634; called by muse, mutect2, varscan2
- SMAD1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV57472535; called by muse, mutect2, varscan2
- SMARCA4 | c.4403C>T p.A1468V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV60800410, COSV60803324; called by muse, mutect2, varscan2
- SMOX | c.997T>G p.S333A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV53866698; called by muse, mutect2, varscan2
- SNAP91 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs565332143, COSV52118903; called by muse, mutect2
- SNTG2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV57997099; called by muse, mutect2, varscan2
- SNX33 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs765168999, COSV57914062; called by muse, mutect2, varscan2
- SOGA3 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs1264323156, COSV64107791; called by muse, varscan2
- SORCS3 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV63809478; called by muse, mutect2, varscan2
- SPAG16 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.361); catalogued as COSV59109417; called by muse, mutect2, varscan2
- SPAM1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV56146106; called by muse, mutect2, varscan2
- SPANXD | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65152580; called by muse, mutect2, varscan2
- SPATA31D1 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as rs766781161, COSV61194847, COSV61198741; called by muse, mutect2, varscan2
- SPC25 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs540046254, COSV56370679; called by muse, mutect2, varscan2
- SPHKAP | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs956059459, COSV60879344; called by muse, mutect2, varscan2
- SPTA1 | c.4957G>A p.E1653K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1425990130, COSV63756950; called by muse, mutect2, varscan2
- SPTA1 | c.2924G>A p.G975E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV63751847; called by muse, mutect2, varscan2
- SPTLC3 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV65467165; called by muse, mutect2, varscan2
- SREK1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52334201; called by muse, mutect2, varscan2
- SSH2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV52177135; called by muse, mutect2, varscan2
- ST18 | c.2626G>A p.G876R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99035476; called by muse, mutect2, varscan2
- ST6GAL1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | PolyPhen benign (0.017); catalogued as COSV51465521; called by muse, mutect2, varscan2
- STAB2 | c.4229C>T p.P1410L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV66343430; called by muse, mutect2, varscan2
- STAB2 | c.7252G>A p.E2418K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.589); catalogued as rs772884738, COSV66343435; called by muse, mutect2, varscan2
- STAC | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV56215100; called by muse, mutect2, varscan2
- STAU2 | c.1204C>T p.P402S (on ENST00000524300 / NM_001164380.2; = p.P370S on NM_014393.2) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV63309959; called by muse, mutect2, varscan2
- STPG2 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV54791676; called by muse, mutect2, varscan2
- STXBP5L | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV56525292; called by muse, mutect2, varscan2
- STXBP5L | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as rs770410696, COSV56525302; called by muse, mutect2, varscan2
- STYK1 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.809); catalogued as COSV50014344; called by muse, mutect2, varscan2
- STYXL2 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as rs1331613197, COSV54807953; called by muse, mutect2, varscan2
- SWT1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1018759543, COSV62257538; called by muse, mutect2, varscan2
- SYCP1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs772498847, COSV65699764; called by muse, mutect2, varscan2
- SYNE1 | c.21715C>T p.Q7239* (on ENST00000367255 / NM_182961.4; = p.Q7168* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV55044875; called by muse, mutect2, varscan2
- SYNE1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747634832, COSV54941372; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SYNGR1 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV59560420; called by muse, mutect2, varscan2
- SYNPO2 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61113680; called by muse, mutect2, varscan2
- TAAR6 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs755041158, COSV51584408; called by muse, mutect2, varscan2
- TAFA1 | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV72039933; called by muse, mutect2, varscan2
- TAGAP | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764717611, COSV57852677; called by muse, mutect2, varscan2
- TANGO6 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV55769587; called by muse, mutect2, varscan2
- TAP2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs746574637, COSV66500363; called by muse, mutect2, varscan2
- TAS2R8 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53690073; called by muse, mutect2, varscan2
- TBC1D32 | c.1186A>G p.K396E | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51549256; called by muse, varscan2
- TBC1D5 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866613522, COSV53750594; called by muse, mutect2
- TBP | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57833017; called by muse, mutect2
- TBX18 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63737561; called by muse, mutect2, varscan2
- TCEA2 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58658697; called by muse, mutect2, varscan2
- TDRD1 | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52593478; called by muse, mutect2, varscan2
- TDRD9 | c.1715T>C p.V572A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as COSV59151868; called by muse, mutect2, varscan2
- TENM1 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64438314; called by muse, mutect2, varscan2
- TENM2 | c.4040G>A p.G1347E (on ENST00000518659 / NM_001122679.2; = p.G1108E on NM_001080428.3) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69136608; called by muse, mutect2, varscan2
- TENM4 | c.4622C>T p.S1541F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV53613322; called by muse, mutect2, varscan2
- TFAP2B | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as CM014600, COSV53829756; called by muse, mutect2, varscan2
- TFAP2C | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52372410; called by muse, mutect2, varscan2
- TG | c.890G>A p.C297Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55087247; called by muse, mutect2, varscan2
- THOC5 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 41/109 reads (38%) | catalogued as COSV63799946; called by muse, mutect2, varscan2
- THRB | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54981457; called by muse, mutect2, varscan2
- THSD7B | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as COSV55715669; called by muse, mutect2, varscan2
- THSD7B | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55715684; called by muse, mutect2, varscan2
- THSD7B | c.3809G>A p.R1270Q (on ENST00000272643; = p.R1268Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs750716218, COSV55711536; called by muse, mutect2, varscan2
- THSD7B | c.4349G>A p.W1450* (on ENST00000272643; = p.W1448* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV55715713; called by muse, mutect2, varscan2
- TLR10 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV58301487; called by muse, mutect2, varscan2
- TMEFF2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as rs149067350; called by muse, mutect2, varscan2
- TMEM135 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.988); catalogued as COSV59703942; called by muse, mutect2, varscan2
- TMEM40 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV53147452; called by muse, mutect2, varscan2
- TMIGD1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV61028982; called by muse, mutect2, varscan2
- TMPRSS12 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs568316978, COSV68256878; called by muse, mutect2
- TMPRSS13 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70627037; called by muse, mutect2, varscan2
- TMX1 | c.315T>C p.H105= | Splice Region (SNP) | VAF 17/38 reads (45%) | catalogued as COSV63284945; called by muse, mutect2, varscan2
- TNC | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as COSV100406515, COSV60787948; called by muse, mutect2, varscan2
- TNFSF8 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56343479; called by muse, mutect2, varscan2
- TNIK | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52689754; called by muse, mutect2, varscan2
- TNKS1BP1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1012483988, COSV64101878; called by muse, mutect2, varscan2
- TP63 | c.579G>A p.T193= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as rs1159440697, COSV53214346; called by muse, mutect2, varscan2
- TRAIP | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58915642; called by muse, mutect2, varscan2
- TRAM2 | c.623T>C p.L208S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV51733960; called by muse, mutect2, varscan2
- TRAV21 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs539988571; called by muse, mutect2
- TRERF1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV61675215; called by muse, mutect2, varscan2
- TRHDE | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs868483120, COSV53840129; called by muse, mutect2, varscan2
- TRPM6 | c.5945G>A p.R1982K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as rs763961048, COSV100664828, COSV62517445; called by muse, mutect2, varscan2
- TRUB2 | c.669A>T p.L223F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV65760043; called by muse, mutect2, varscan2
- TSHZ1 | c.319T>A p.S107T (on ENST00000580243 / NM_001308210.2; = p.S62T on NM_005786.6) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.046); catalogued as COSV59013732; called by muse, mutect2, varscan2
- TTC39A | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.04); catalogued as COSV52960125; called by muse, mutect2, varscan2
- TTC6 | c.265C>T p.H89Y (on ENST00000267368; = p.H1358Y on NM_001310135.3) | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57451218; called by muse, mutect2, varscan2
- TTLL7 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV53087084; called by muse, mutect2, varscan2
- TTN | c.97639G>A p.E32547K (on ENST00000591111; = p.E25123K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | PolyPhen benign (0.023); catalogued as rs577667352, COSV60213796; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.26663C>T p.P8888L (on ENST00000591111; = p.P7961L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | PolyPhen probably damaging (0.999); catalogued as rs758238716, COSV60213888; called by muse, mutect2, varscan2
- TTN | c.25400G>A p.W8467* (on ENST00000591111; = p.W7540* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV59876824; called by muse, mutect2, varscan2
- TTN | c.24460G>A p.E8154K (on ENST00000591111; = p.E7227K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | PolyPhen benign (0.003); catalogued as COSV60213911; called by muse, mutect2, varscan2
- TTN | c.6890G>A p.G2297E (on ENST00000591111; = p.G2251E on NM_003319.4) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | PolyPhen probably damaging (1); catalogued as COSV59874453; called by muse, mutect2, varscan2
- TTN | c.6388G>A p.E2130K (on ENST00000591111; = p.E2084K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | PolyPhen probably damaging (0.994); catalogued as rs762914675, COSV60092129; called by muse, mutect2, varscan2
- TTN | c.4625C>T p.S1542L (on ENST00000591111; = p.S1496L on NM_003319.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | PolyPhen benign (0.306); catalogued as COSV60079968; called by muse, mutect2, varscan2
- TTN | c.4112G>A p.G1371E (on ENST00000591111; = p.G1325E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | PolyPhen probably damaging (1); catalogued as rs267599090, COSV60214092; called by muse, mutect2, varscan2
- TTYH2 | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.451); catalogued as COSV53912127; called by muse, mutect2, varscan2
- TULP1 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.154); catalogued as rs1292429761, COSV57693316; called by muse, mutect2, varscan2
- TUSC3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs749336367, COSV65877700, COSV65883577; called by muse, mutect2, varscan2
- TYRO3 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55485239; called by muse, mutect2, varscan2
- UBE2V2 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72878728, COSV72878760; called by muse, mutect2
- UBR4 | c.12721C>T p.L4241F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64395028; called by muse, mutect2
- UCK1 | c.367T>C p.L123= | Splice Region (SNP) | VAF 6/37 reads (16%) | catalogued as COSV64736016; called by muse, mutect2
551 further variants in this file (87 protein-altering or splice-affecting, 431 silent, 33 other) are not listed here.
